Surgical pathology report (de-identified scan), TCGA case TCGA-EI-6514, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-EI-6514-01A (Primary Tumor).

Examination: Histopathological examination

Material: 1. Multiple organ resection – colon and sigmoid

Physician in charge:

Expected time of examination:

Clinical diagnosis: Cancer of the rectosigmoid junction.

TCGA – EI – 6514

Macroscopic description:

15.8 cm length of the large intestine with a fragment of the mesorectum sized 17 x 6 x 3 cm. Ulcerous tumour sized 6.3 x 6.6 x 0.9 cm found in the mucosa. The lesion surrounds 100% of the intestine circumference, located 0.5 cm from one of the excision lines and 2.9 cm from the opposite line.

Microscopic description:

Adenocarcinoma tubulopapillare (G2).

Infiltratio carcinomatosa telae adiposae mesenterii (spec. B).

Excision lines free of neoplastic lesions.

Lymphonodulitis reactiva (No VIII).

Histopathological diagnosis:

Adenocarcinoma tubulopapillare coli. Tubulopapillar adenocarcinoma of the colon.

(G2; Dukes B; Astler-Coller B2; pT3; pN0).

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file da5e8f9a-4301-4688-a07a-00c03bb1d87c (TCGA-EI-6514.044DBE06-FB46-4A96-8578-A585CC122FD4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).